Somatic mutation profile of tumor specimen C3L-06176-01 (aliquot CPT0456580008) from CPTAC case C3L-06176, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 44.5 years (16,257 days).
Specimen C3L-06176-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07f077db-d108-433b-8df4-f0e0ecd0d551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06176-31 (Blood Derived Normal), aliquot CPT0456670003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c7272fb-a8ba-4156-baed-ec59534f5096

The open-access MAF lists 902 somatic variants for this specimen: 570 protein-altering or splice-affecting, 300 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 509, Silent 300, Nonsense Mutation 40, Intron 19, Splice Region 11, Splice Site 6, 5'Flank 4, 3'UTR 3, 5'UTR 3, RNA 2, Nonstop Mutation 1, Frame Shift Del 1.

Variants (750 of 902; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AACS | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768647856; called by muse, mutect2, varscan2
- ABCC12 | c.3806G>A p.R1269Q | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139931213; called by muse, mutect2, varscan2
- ACOT9 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV60537944; called by muse, mutect2
- ADAM29 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63666150; called by muse, mutect2, varscan2
- ADAM29 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as rs1486312556; called by muse, mutect2
- ADAM29 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs1409851955; called by muse, mutect2
- ADAMTS19 | c.2924G>A p.R975Q | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs145234388, COSV50736858; called by muse, mutect2, varscan2
- ADAMTS8 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs767473536, COSV57295086; called by muse, mutect2, varscan2
- ADGRG4 | c.2336G>A p.R779K | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.124); catalogued as COSV54954494; called by muse, mutect2, varscan2
- ADGRL3 | c.423G>A p.M141I (on ENST00000506720 / NM_001322402.2; = p.M73I on NM_015236.6) | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101547416; called by muse, mutect2, varscan2
- ADGRV1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 10/312 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as COSV67979664; called by muse, mutect2
- AGGF1 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.223); catalogued as rs762424751; called by muse, mutect2, varscan2
- AHR | c.1199C>G p.T400R | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs757131411, COSV54122212; called by muse, varscan2
- ALG10B | c.472T>C p.F158L | Missense Mutation (SNP) | VAF 97/335 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV58143439; called by muse, mutect2, varscan2
- ANKRD66 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1256054395; called by muse, mutect2
- APAF1 | c.2812C>T p.L938F (on ENST00000551964 / NM_181861.2; = p.L884F on NM_001160.3) | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs1403684533, COSV59663962; called by muse, mutect2
- AREG | c.409A>T p.R137* | Nonsense Mutation (SNP) | VAF 18/376 reads (5%) | catalogued as rs1278052668; called by muse, mutect2
- ARHGEF28 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1395400149, COSV55270437; called by muse, mutect2
- ARMC4 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758151554, COSV59462659; called by muse, mutect2, varscan2
- ARNTL2 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1261354324; called by muse, mutect2, varscan2
- ASH1L | c.8737C>T p.P2913S (on ENST00000368346 / NM_001366177.2; = p.P2908S on NM_018489.3) | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as rs1176189509, COSV100853186; called by muse, mutect2
- ASTN2 | c.2240G>A p.G747E (on ENST00000313400 / NM_001365069.1; = p.G696E on NM_014010.5) | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs866501849; called by muse, mutect2, varscan2
- ASXL1 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.121); catalogued as COSV60107323; called by muse, mutect2
- ATP10D | c.3976C>T p.P1326S | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV56694872; called by muse, mutect2, varscan2
- BAHD1 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs200344667; called by muse, mutect2, varscan2
- BASP1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs563948276; called by muse, mutect2, varscan2
- BHMT2 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363554879; called by muse, mutect2, varscan2
- BIRC6 | c.12145G>A p.G4049S | Missense Mutation (SNP) | VAF 85/351 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs758549232, COSV66042904; called by muse, mutect2, varscan2
- BRINP1 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs866443418, COSV99776336; called by muse, mutect2
- BRWD3 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64749411; called by muse, mutect2, varscan2
- C7orf26 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.7); catalogued as rs1261206780; called by muse, mutect2
- CACNA1C | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100219351; called by muse, mutect2, varscan2
- CACNA2D3 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as COSV99876828; called by muse, mutect2, varscan2
- CACNA2D4 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.577); catalogued as COSV54957701; called by muse, mutect2, varscan2
- CAD | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 66/313 reads (21%) | catalogued as COSV99254548; called by muse, mutect2, varscan2
- CBLN2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 80/269 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs991232543; called by muse, mutect2, varscan2
- CCDC141 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV55375639, COSV55378471; called by muse, mutect2
- CCDC168 | c.13984C>T p.H4662Y | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.029); catalogued as rs1435748601, COSV59424895; called by muse, mutect2, varscan2
- CGN | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs543323652, COSV54969616; called by muse, mutect2, varscan2
- CHML | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59362998; called by muse, mutect2, varscan2
- CHRM2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100281050; called by muse, mutect2, varscan2
- CLCN2 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as rs967058477; called by muse, mutect2, varscan2
- CLDN10 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65297968; called by muse, mutect2
- CLDN19 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); catalogued as rs780278993; called by muse, mutect2, varscan2
- CLMN | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1478993847; called by muse, mutect2, varscan2
- CNBD1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1190645586, COSV73074002; called by muse, mutect2
- CNGB3 | c.959A>T p.N320I | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs879004437; called by muse, mutect2
- CNTN2 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs1305299399; called by muse, mutect2
- CNTN5 | c.2168C>A p.P723Q | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679719; called by mutect2, varscan2
- CNTNAP5 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV70498906; called by muse, varscan2
- CNTNAP5 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1486425523, COSV70470109; called by muse, mutect2
- COL11A1 | c.4465G>A p.G1489R | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV62183742; called by muse, mutect2, varscan2
- COL21A1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV55158678, COSV99777539; called by muse, mutect2, varscan2
- COL4A3 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772708743, CM151508; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COPZ2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs1284908422, COSV50058038; called by muse, mutect2
- CPNE7 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371577272; called by muse, mutect2, varscan2
- CRACD | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 86/426 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.095); catalogued as rs547087897; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2, varscan2
- CSNK1D | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as rs1195517111; called by muse, mutect2
- CYP4F22 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV54109999; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2
- DCX | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs727503897, COSV100576494, COSV57567054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX4 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61756511; called by muse, mutect2, varscan2
- DGKH | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369495113; called by muse, mutect2, varscan2
- DHCR7 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM052221, COSV62795481; called by muse, mutect2, varscan2
- DKK2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53396006; called by muse, mutect2
- DMBT1 | c.7117C>T p.Q2373* (on ENST00000338354 / NM_001377530.1; = p.Q1616* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 88/274 reads (32%) | catalogued as COSV57534557; called by muse, mutect2, varscan2
- DMD | c.2888C>T p.S963F | Missense Mutation (SNP) | VAF 87/361 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs1429983365; called by muse, mutect2, varscan2
- DMXL2 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs767380260; called by muse, mutect2, varscan2
- DNAH12 | c.8203G>A p.V2735I (on ENST00000351747; = p.V3603I on NM_001366028.2) | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.19); catalogued as rs1471001608; called by muse, mutect2, varscan2
- DNAH3 | c.11504C>T p.S3835F | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54540232; called by muse, mutect2, varscan2
- DNAH5 | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371700933; called by muse, mutect2, varscan2
- DNAH8 | c.12947C>T p.S4316L | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765766734, COSV59443932; called by muse, mutect2
- DOK5 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV52818705; called by muse, mutect2
- DPPA5 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV64875388; called by muse, mutect2, varscan2
- DRD5 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1464125995, COSV58580139; called by muse, mutect2
- DSCAM | c.5680C>T p.R1894W | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1194037057, COSV68023366; called by muse, mutect2, varscan2
- DSG1 | c.2174G>A p.G725D | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1411440944; called by muse, mutect2, varscan2
- EFCAB12 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV100394435, COSV100394598; called by muse, mutect2
- EFCAB13 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1396501444, COSV58952274; called by muse, mutect2
- EPHA6 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 75/335 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV67560246; called by muse, mutect2, varscan2
- ERICH3 | c.2549G>A p.R850K | Missense Mutation (SNP) | VAF 106/499 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs923534263; called by muse, mutect2, varscan2
- ESRRG | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs1435255843; called by muse, mutect2, varscan2
- EYA1 | c.1475+1G>A p.X492_splice | Splice Site (SNP) | VAF 24/311 reads (8%) | catalogued as CS132731, COSV58165986; called by muse, mutect2
- FAM153B | c.1121G>A p.R374Q (on ENST00000253490; = p.R297Q on NM_001265615.1) | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.622); catalogued as rs1361596749; called by muse, mutect2, varscan2
- FAM160A1 | c.1092C>G p.H364Q | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101475095; called by muse, mutect2, varscan2
- FBXL19 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs779861596; called by muse, mutect2, varscan2
- FCAR | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 115/460 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.395); catalogued as rs144534044, COSV62032213; called by muse, mutect2, varscan2
- FCGR3B | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 31/318 reads (10%) | catalogued as COSV54209892; called by muse, mutect2, varscan2
- FCHSD2 | c.285G>T p.M95I | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs755756437; called by muse, mutect2, varscan2
- FCRL5 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 11/339 reads (3%) | catalogued as rs1338242004, COSV62515874; called by muse, mutect2
- FGD5 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53254140; called by muse, mutect2, varscan2
- FHDC1 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52599255; called by muse, mutect2
- FMO5 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.145); catalogued as rs1553924994; called by muse, mutect2, varscan2
- FN1 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100118550, COSV60552664; called by muse, mutect2, varscan2
- FREM1 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV66530059; called by muse, mutect2, varscan2
- GADL1 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 15/308 reads (5%) | catalogued as COSV56985869; called by muse, mutect2
- GALNT1 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1430687191; called by muse, mutect2
- GALNT13 | c.780G>A p.W260* | Nonsense Mutation (SNP) | VAF 57/303 reads (19%) | catalogued as COSV67209955, COSV67241776; called by muse, mutect2, varscan2
- GAPDH | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as rs1480299798; called by muse, varscan2
- GDF5 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 22/441 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV104428365; called by muse, mutect2
- GGT2 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as rs540379195; called by mutect2, varscan2
- GPAT2 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558686618; called by muse, mutect2, varscan2
- GPC5 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 63/298 reads (21%) | catalogued as rs1302889205; called by muse, mutect2, varscan2
- GPR149 | c.2090G>A p.R697K | Missense Mutation (SNP) | VAF 109/464 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1337658235; called by muse, mutect2, varscan2
- GRIN2A | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 93/383 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58022258; called by muse, mutect2, varscan2
- HEPACAM2 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 67/331 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1034180298, COSV101085500; called by muse, mutect2, varscan2
- HEPH | c.2863G>A p.D955N (on ENST00000343002; = p.D688N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV57959762; called by muse, mutect2, varscan2
- HGD | c.87+1G>A p.X29_splice | Splice Site (SNP) | VAF 49/269 reads (18%) | catalogued as CS144681; called by muse, mutect2, varscan2
- HTR4 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 107/378 reads (28%) | PolyPhen benign (0); catalogued as rs547983930; called by muse, mutect2, varscan2
- IGFN1 | c.3001C>T p.L1001F (on ENST00000295591 / NM_001367841.1; = p.L3458F on NM_001164586.2) | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.788); catalogued as COSV55167583; called by muse, mutect2, varscan2
- IGKV3-15 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs745796620; called by muse, mutect2, varscan2
- INTS3 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 99/447 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750118134; called by muse, mutect2, varscan2
- IPO9 | c.912T>C p.F304= | Splice Region (SNP) | VAF 53/185 reads (29%) | catalogued as rs971767448, COSV64233477; called by muse, mutect2, varscan2
- ITGAL | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.966); catalogued as COSV63324829; called by muse, mutect2
- ITGAL | c.2735C>T p.S912L | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV63323822; called by muse, mutect2, varscan2
- KCNB2 | c.2683C>T p.H895Y | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs866710129, COSV73049516; called by muse, mutect2, varscan2
- KCND2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV58573780; called by muse, mutect2
- KCNH6 | c.2434C>T p.Q812* | Nonsense Mutation (SNP) | VAF 16/457 reads (4%) | catalogued as rs1269958602; called by muse, mutect2
- KIAA1549 | c.5749G>A p.D1917N (on ENST00000422774 / NM_001164665.2; = p.D1901N on NM_020910.3) | Missense Mutation (SNP) | VAF 143/555 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1245655177; called by muse, mutect2, varscan2
- KLHL22 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1205647733, COSV61021670; called by muse, mutect2, varscan2
- KMT2D | c.12413C>T p.S4138F | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1281537769, COSV56423898; called by muse, mutect2, varscan2
- KNG1 | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs866217976, COSV99405197; called by muse, mutect2, varscan2
- KPNA7 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs936390745; called by muse, mutect2, varscan2
- KPRP | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 98/354 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1430220937, COSV64221195; called by muse, mutect2, varscan2
- KY | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 87/393 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV101414993; called by muse, mutect2, varscan2
- LAMA3 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 19/481 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.786); catalogued as rs1437074022; called by muse, mutect2
- LAMA5 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190038248; called by muse, mutect2, varscan2
- LETM2 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV99907689; called by muse, mutect2, varscan2
- LGI2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs757175261; called by muse, mutect2, varscan2
- LRFN2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as COSV57827803; called by muse, mutect2, varscan2
- LRFN5 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 47/345 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs749539710, COSV53271146; called by muse, mutect2, varscan2
- LRRIQ3 | c.1707G>A p.M569I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1179689038, COSV63042900; called by muse, mutect2, varscan2
- LTN1 | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200123955, COSV63732912; called by muse, mutect2, varscan2
- MAOB | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 72/260 reads (28%) | catalogued as COSV65207253; called by muse, mutect2, varscan2
- MARCHF10 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs746673242, COSV60885717, COSV60890084; called by muse, mutect2
- MCTP1 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs370579973; called by muse, mutect2, varscan2
- MCTP1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56512108, COSV56537723; called by muse, mutect2, varscan2
- MCTP1 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 40/173 reads (23%) | catalogued as rs868189017, COSV56516786, COSV56524859; called by muse, mutect2, varscan2
- MECOM | c.746G>A p.G249E (on ENST00000468789 / NM_001105078.4; = p.G437E on NM_004991.4) | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52969254; called by muse, mutect2, varscan2
- MECP2 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs61749739; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- MED13 | c.4226G>A p.R1409Q | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs779513017; called by muse, mutect2, varscan2
- MEFV | c.2032G>A p.G678R | Missense Mutation (SNP) | VAF 47/453 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54827084; called by muse, mutect2
- MEOX1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745469637, COSV59357377; called by muse, mutect2, varscan2
- MEP1A | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs765090084, COSV57919378, COSV57921600; called by muse, varscan2
- MFSD1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 20/580 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51839622; called by muse, mutect2
- MISP | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV53121711; called by muse, mutect2
- MSTO1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1369814493, COSV55471744; called by muse, mutect2
- MTF1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 93/416 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV100888573; called by muse, mutect2, varscan2
- MTUS2 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 53/492 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV70914864; called by muse, mutect2
- MTUS2 | c.2149G>A p.G717R | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs947968241; called by muse, mutect2, varscan2
- MUC12 | c.15139G>A p.E5047K (on ENST00000379442; = p.E4904K on NM_001164462.1) | Missense Mutation (SNP) | VAF 17/468 reads (4%) | SIFT deleterious (0.02); catalogued as rs1474192430; called by muse, mutect2
- MUC16 | c.38368G>A p.E12790K | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV67478180; called by muse, mutect2, varscan2
- MUC21 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 137/603 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.463); catalogued as rs531044924; called by muse, mutect2, varscan2
- MUC4 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 20/606 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.494); catalogued as COSV100641447; called by muse, mutect2
- MYH1 | c.3704T>G p.L1235R | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs188804570, COSV99876755; called by muse, mutect2, varscan2
- MYH1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56852668; called by muse, mutect2, varscan2
- MYLK | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs1397757032, COSV60609666; called by muse, mutect2, varscan2
- MYOM3 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs767200002; called by muse, mutect2, varscan2
- NBL1 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV57029524; called by muse, mutect2, varscan2
- NCAM1 | c.1824C>T p.V608= (on ENST00000316851 / NM_181351.5; = p.V598= on NM_000615.7) | Splice Region (SNP) | VAF 32/190 reads (17%) | catalogued as rs902863832, COSV57515527; called by muse, mutect2, varscan2
- NCR3LG1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs772007713; called by muse, mutect2, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 98/402 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, varscan2
- NIPAL2 | c.880+1G>A p.X294_splice | Splice Site (SNP) | VAF 61/236 reads (26%) | catalogued as rs1218469853; called by muse, mutect2, varscan2
- NMUR2 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150236745, COSV54921872; called by muse, mutect2, varscan2
- NOTCH2 | c.6446C>T p.S2149F | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56682321; called by muse, mutect2
- NUP153 | c.3989G>A p.S1330N | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1009376501; called by muse, mutect2
- NUP153 | c.3158T>C p.I1053T | Missense Mutation (SNP) | VAF 86/372 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs146551209; called by muse, mutect2, varscan2
- NYNRIN | c.3823C>T p.L1275F | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as rs1472146683, COSV66843393; called by muse, mutect2, varscan2
- OR11H12 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 61/513 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1298787003, COSV101612448; called by muse, mutect2, varscan2
- OR13C8 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100623048, COSV58611198, COSV58611995; called by muse, mutect2, varscan2
- OR1N2 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV65461063; called by muse, mutect2, varscan2
- OR1S1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1406919672, COSV100515353, COSV58706707; called by muse, mutect2
- OR1S1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 41/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58706727; called by muse, mutect2
- OR4X2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166747967, COSV56582293; called by muse, mutect2, varscan2
- OR51I1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201278585; called by muse, mutect2, varscan2
- OR5D14 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748386955, COSV59455727, COSV59457599; called by muse, mutect2, varscan2
- OR5M1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV73202490; called by muse, mutect2, varscan2
- OR5M3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 95/340 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169805435; called by muse, mutect2, varscan2
- P3R3URF-PIK3R3 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 88/332 reads (27%) | catalogued as rs531318874; called by muse, varscan2
- PACRG | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs1192881334; called by muse, mutect2, varscan2
- PAM | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs1478977284; called by muse, mutect2, varscan2
- PCDHB4 | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 73/470 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1372143357; called by muse, mutect2, varscan2
- PCDHB7 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50754021, COSV50784549; called by muse, mutect2
- PCDHGA11 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs764728654, COSV53921115; called by muse, mutect2, varscan2
- PDGFD | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as COSV56397278; called by muse, mutect2, varscan2
- PGR | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54809013; called by muse, mutect2
- PGS1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753343685; called by muse, mutect2, varscan2
- PKHD1 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1384539153; called by muse, mutect2, varscan2
- PLCB3 | c.3409C>T p.R1137C | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254014643; called by muse, mutect2, varscan2
- PLCH2 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 55/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1353252987, COSV53940286; called by muse, mutect2, varscan2
- POGK | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 80/431 reads (19%) | catalogued as COSV63311554; called by muse, mutect2, varscan2
- POLE | c.6743C>A p.T2248N | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV57674454, COSV57693487; called by muse, mutect2, varscan2
- POLR2F | c.453G>A p.R151= | Splice Region (SNP) | VAF 81/357 reads (23%) | catalogued as rs1176755329; called by muse, mutect2, varscan2
- PPP1R3F | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1557118811; called by muse, mutect2
- PRKAA2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763667032, COSV100983135; called by muse, mutect2, varscan2
- PTPN18 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758537112; called by muse, mutect2, varscan2
- QRFPR | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 11/332 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100544007; called by muse, mutect2
- RBM33 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs899410742; called by muse, mutect2
- REN | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 128/370 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV65817710; called by muse, mutect2, varscan2
- RGS7 | c.1319G>A p.R440K | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV100463890; called by muse, mutect2, varscan2
- RP1L1 | c.1373G>A p.S458N | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV66755460; called by muse, mutect2
- RSPO3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs1441727997, COSV63152217; called by muse, mutect2, varscan2
- RYR2 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs765102386, COSV100772577, COSV63674230; ClinVar: uncertain significance; called by muse, mutect2
- SALL1 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51762189; called by muse, mutect2, varscan2
- SAMD9L | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59086082; called by muse, mutect2, varscan2
- SCN7A | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV69273032; called by muse, mutect2
- SDK2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 84/349 reads (24%) | catalogued as rs1314025937; called by muse, mutect2
- SEC31A | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV52347594; called by muse, mutect2, varscan2
- SFTPB | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100667302; called by muse, mutect2
- SGSM1 | c.2737G>A p.E913K (on ENST00000400359 / NM_001039948.4; = p.E852K on NM_133454.3) | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs1403468660; called by muse, mutect2
- SI | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.588); catalogued as COSV52285951; called by muse, mutect2, varscan2
- SLC10A2 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99808329; called by muse, mutect2, varscan2
- SLC26A8 | c.2730G>A p.M910I | Missense Mutation (SNP) | VAF 15/465 reads (3%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as rs865836060; called by muse, mutect2
- SLC38A5 | c.1212C>T p.I404= | Splice Region (SNP) | VAF 82/284 reads (29%) | catalogued as rs201040223, COSV58333543; called by muse, mutect2, varscan2
- SLC39A9 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750445371; called by muse, mutect2, varscan2
- SLC5A8 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142965122, COSV73311292; called by muse, mutect2, varscan2
- SLCO5A1 | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.261); catalogued as rs141622109; called by muse, mutect2, varscan2
- SMARCA4 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 75/430 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs988231473; called by muse, mutect2, varscan2
- SMCHD1 | c.5737C>T p.R1913C | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as rs764493125, COSV57972543; called by muse, mutect2, varscan2
- SPHKAP | c.2131C>T p.Q711* | Nonsense Mutation (SNP) | VAF 101/362 reads (28%) | catalogued as rs1452524102, COSV60891092; called by muse, mutect2, varscan2
- SPPL2C | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 37/711 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV61291819; called by muse, mutect2
- SPSB4 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 120/480 reads (25%) | catalogued as COSV60147586; called by muse, mutect2, varscan2
- SV2C | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.604); catalogued as COSV59216325, COSV59230261; called by muse, mutect2, varscan2
- SYNJ2 | c.3685C>T p.R1229C | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1156811180, COSV100840154; called by muse, mutect2
- TAPBPL | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1263369071, COSV56947233; called by muse, mutect2, varscan2
- TAZ | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs781958108; called by muse, mutect2
- TBC1D8B | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs1025911576; called by muse, mutect2, varscan2
- TBC1D8B | c.3010C>T p.H1004Y | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV52175850, COSV52176230; called by muse, mutect2, varscan2
- TCP11L1 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV57515292; called by muse, mutect2
- TENM1 | c.4555C>T p.R1519C | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64431715; called by muse, mutect2, varscan2
- TENM3 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs866683879; called by muse, mutect2, varscan2
- THSD7B | c.3239C>T p.S1080F (on ENST00000272643; = p.S1078F on NM_001316349.2) | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs267598897; called by muse, mutect2, varscan2
- TMEM132D | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV104431257, COSV67162378; called by muse, mutect2
- TMEM63C | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53610024; called by muse, mutect2, varscan2
- TNNI3K | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53950159, COSV53950170; called by muse, mutect2, varscan2
- TPTE | c.367C>T p.P123S (on ENST00000618007 / NM_199261.4; = p.P105S on NM_199259.4) | Missense Mutation (SNP) | VAF 57/652 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs778635152; called by muse, mutect2
- TRAV26-1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1433701912; called by muse, mutect2, varscan2
- TRPC7 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as rs745468742, COSV61456935; called by muse, mutect2, varscan2
- TTBK1 | c.2611C>T p.R871W | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV52488708; called by muse, mutect2, varscan2
- TTN | c.51637G>A p.E17213K (on ENST00000591111; = p.E9789K on NM_003319.4) | Missense Mutation (SNP) | VAF 85/374 reads (23%) | PolyPhen possibly damaging (0.562); catalogued as COSV59933833; called by muse, mutect2, varscan2
- TTN | c.5107C>T p.P1703S (on ENST00000591111; = p.P1657S on NM_003319.4) | Missense Mutation (SNP) | VAF 96/425 reads (23%) | PolyPhen probably damaging (0.998); catalogued as rs898070344; called by muse, mutect2, varscan2
- UGT3A2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as COSV56933651; called by muse, mutect2, varscan2
- USP15 | c.992C>T p.P331L (on ENST00000280377 / NM_001351159.2; = p.P302L on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV99740004; called by muse, mutect2, varscan2
- USP29 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.437); catalogued as rs866020470, COSV99517859; called by muse, mutect2, varscan2
- VEPH1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV100747896; called by muse, mutect2
- WASHC2A | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 15/436 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1382067795; called by muse, mutect2
- WDR25 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1276447207; called by muse, mutect2, varscan2
- WDR88 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs772240791; called by muse, mutect2, varscan2
- WNT7A | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 15/435 reads (3%) | catalogued as rs1483590773, COSV53197674; called by muse, mutect2
- WSCD1 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 14/490 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as COSV58498421; called by muse, mutect2
- ZBED5 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs771841499; called by muse, mutect2, varscan2
- ZBED9 | c.3329G>A p.S1110N | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1310491000; called by muse, mutect2, varscan2
- ZBTB46 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 101/510 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV55514740, COSV55515116; called by muse, mutect2, varscan2
- ZBTB46 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV55515405; called by muse, mutect2
- ZNF260 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 88/383 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs1401257927; called by muse, mutect2, varscan2
- ZNF425 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65202674; called by muse, mutect2, varscan2
- ZNF560 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV56870504; called by muse, mutect2, varscan2
- ZNF613 | c.1532C>T p.P511L (on ENST00000293471 / NM_001031721.4; = p.P475L on NM_024840.4) | Missense Mutation (SNP) | VAF 43/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781246593; called by muse, mutect2, varscan2
- ZNF727 | c.1382T>A p.F461Y | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV101407058; called by muse, mutect2, varscan2
- ZNF732 | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV69954963; called by muse, mutect2, varscan2
- ZNF735 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV70035365; called by muse, mutect2, varscan2
- ZNF804A | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV56457717; called by muse, mutect2, varscan2
- ZNF853 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 119/371 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs779484251; called by muse, mutect2, varscan2
- ZNF99 | c.2179C>T p.H727Y | Missense Mutation (SNP) | VAF 23/438 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs1334096852, COSV68055976; called by muse, mutect2
- ABCA2 | c.239C>T p.S80F (on ENST00000614293; = p.S50F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2
- AC011462.1 | c.1164G>A p.W388* | Nonsense Mutation (SNP) | VAF 31/452 reads (7%) | called by muse, mutect2
- ACACA | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ACAD11 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- ACSM3 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTRT1 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.42); called by muse, mutect2
- ADAMTS20 | c.4046C>T p.P1349L | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS9 | c.3851C>T p.P1284L | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRF5 | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRV1 | c.8107G>A p.G2703R | Missense Mutation (SNP) | VAF 51/388 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGGF1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- AIFM3 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 84/387 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMPD3 | c.2128G>A p.E710K (on ENST00000396553 / NM_001025389.2; = p.E719K on NM_000480.3) | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ANK1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- ANKRD11 | c.6271C>T p.Q2091* | Nonsense Mutation (SNP) | VAF 99/388 reads (26%) | called by muse, mutect2, varscan2
- ANO9 | c.450G>C p.R150S | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AREG | c.408T>A p.N136K | Missense Mutation (SNP) | VAF 18/377 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2
- ARHGEF35 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by mutect2, varscan2
- ARID1A | c.2155G>A p.V719M | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2
- ARID3C | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARMC5 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 12/422 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- ASXL3 | c.5155G>A p.A1719T | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP1A2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- BCL9L | c.4391C>T p.P1464L | Missense Mutation (SNP) | VAF 125/449 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- BHLHE41 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); called by muse, mutect2
- BICRAL | c.3172C>T p.H1058Y | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); called by muse, mutect2
- BRD4 | c.2510C>T p.P837L | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- BTAF1 | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTBD8 | c.1741T>C p.S581P (on ENST00000636805 / NM_001376131.1; = p.S68P on NM_015237.4) | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTNL8 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BX276092.9 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- C2CD2L | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CACNA1E | c.5248G>A p.E1750K | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CAPS2 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCDC168 | c.20737T>A p.Y6913N | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC168 | c.16423G>A p.D5475N | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.592); called by muse, mutect2
- CCDC39 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.028); called by muse, mutect2
- CCDC71 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC87 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 109/391 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CD207 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CDH7 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CDK12 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDYL2 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CENPT | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP112 | c.2783C>T p.S928F (on ENST00000392769 / NM_001353127.1; = p.S184F on NM_001037325.3) | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CFAP157 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CFAP47 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 70/240 reads (29%) | called by muse, mutect2, varscan2
- CNTN2 | c.796A>G p.N266D | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNTN4 | c.2996G>A p.G999E | Missense Mutation (SNP) | VAF 14/343 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- CNTN5 | c.2722G>A p.G908R | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL4A4 | c.3680G>A p.G1227E | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A4 | c.2455G>A p.G819S | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A3 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL6A5 | c.7193T>C p.F2398S (on ENST00000312481; = p.F2394S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL9A2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 132/396 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CORO2A | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPLANE1 | c.7732G>C p.V2578L | Missense Mutation (SNP) | VAF 15/399 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.04); called by muse, mutect2
- CPT1C | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CRACDL | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CRLF2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CRNN | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 94/422 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CROCC2 | c.1464G>A p.R488= | Splice Region (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- CSF2RB | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 102/415 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSMD2 | c.833T>A p.I278N | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CYP19A1 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- CYP1A2 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- DCLK2 | c.841T>A p.F281I | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DCLK2 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by mutect2, varscan2
- DGKH | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKQ | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- DGUOK | c.620C>A p.A207D | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DHX16 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 102/491 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DLGAP2 | c.2128C>T p.L710F | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH12 | c.8204T>C p.V2735A (on ENST00000351747; = p.V3603A on NM_001366028.2) | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- DNAH9 | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 70/383 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DOT1L | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DPT | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPY30 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2
- DRC1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- DSCAM | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP14 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ECT2 | c.1333C>A p.P445T (on ENST00000392692 / NM_001349098.2; = p.P414T on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- EGFL6 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ELL | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 118/447 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELP3 | c.1093_1095dup p.V365dup | In Frame Ins (INS) | VAF 48/219 reads (22%) | called by mutect2, pindel, varscan2
- ENAM | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM186B | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM47B | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 77/307 reads (25%) | called by muse, mutect2, varscan2
- FAR2 | c.1258-1G>A p.X420_splice | Splice Site (SNP) | VAF 60/203 reads (30%) | called by muse, mutect2, varscan2
- FAT2 | c.11809G>A p.E3937K | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- FBXO38 | c.3070C>T p.P1024S (on ENST00000340253 / NM_205836.3; = p.P949S on NM_030793.5) | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FCHSD2 | c.284T>A p.M95K | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- FCRL1 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- FCRLA | c.702G>T p.K234N (on ENST00000367959; = p.K211N on NM_032738.4) | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FER1L5 | c.3286A>C p.T1096P (on ENST00000623019; = p.T1069P on NM_001293083.2) | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FGB | c.1004T>G p.M335R | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, varscan2
- FGD1 | c.426A>C p.E142D | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by mutect2, varscan2
- FIZ1 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 20/417 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- FLG | c.8578G>A p.E2860K | Missense Mutation (SNP) | VAF 20/534 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.169); called by muse, mutect2
- FMN2 | c.5105C>T p.S1702L | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- FOXB2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FREM3 | c.6104G>A p.R2035K | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRYL | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- FSHR | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- FSTL3 | c.664T>G p.C222G | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GAPT | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GAS2L3 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GGT5 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 59/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GLI1 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 25/439 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.327); called by muse, mutect2
- GMEB2 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GNPAT | c.1316T>G p.I439S | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1461G>A p.W487* | Nonsense Mutation (SNP) | VAF 118/900 reads (13%) | called by muse, mutect2, varscan2
- GRB7 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRXCR1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- GULP1 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 33/370 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); called by muse, mutect2
- GYG1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAPLN4 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 103/461 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HECW1 | c.2135G>A p.R712K | Missense Mutation (SNP) | VAF 60/423 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HEG1 | c.2768C>T p.S923L | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2
- HOXD8 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICAM1 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2
- IGF2R | c.4437C>G p.S1479R | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- IGKV1D-8 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- IGSF1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- IGSF9 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 54/217 reads (25%) | called by muse, mutect2, varscan2
- IL17RC | c.1354G>A p.E452K (on ENST00000295981 / NM_153461.4; = p.E366K on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- IL18R1 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); called by muse, mutect2
- INSL4 | c.198A>G p.E66= | Splice Region (SNP) | VAF 57/171 reads (33%) | called by muse, mutect2, varscan2
- IPP | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- IQCE | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JAK1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KANK4 | c.2881A>G p.K961E | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KANSL1 | c.2866C>T p.P956S (on ENST00000574590 / NM_001193465.2; = p.P957S on NM_015443.4) | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNQ3 | c.1100A>C p.H367P | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIF26A | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- KIF26B | c.5120G>A p.G1707E | Missense Mutation (SNP) | VAF 128/602 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- KIR3DL1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 25/575 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- KLC4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- LAMA2 | c.4189G>A p.G1397R | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAYN | c.844C>T p.H282Y (on ENST00000375615 / NM_001258390.1; = p.H274Y on NM_178834.5) | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIFR | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LONP2 | c.984C>T p.D328= | Splice Region (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- LRIF1 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- LRRC8D | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LY75 | c.3063G>C p.K1021N | Missense Mutation (SNP) | VAF 93/408 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MADD | c.2272A>T p.I758F | Missense Mutation (SNP) | VAF 70/483 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- MAGEC3 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 74/475 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MAGEE1 | c.1741A>T p.M581L | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MAST2 | c.3188-1G>A p.X1063_splice | Splice Site (SNP) | VAF 58/221 reads (26%) | called by muse, mutect2, varscan2
- MCTP1 | c.2732G>A p.W911* | Nonsense Mutation (SNP) | VAF 59/254 reads (23%) | called by muse, mutect2, varscan2
- MEI1 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEI1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MEI4 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MEOX1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 115/450 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MMADHC | c.555T>A p.D185E | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MORC1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPDZ | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2
- MPO | c.2200C>G p.P734A | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MROH1 | c.3149A>G p.Q1050R | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MTUS2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- MUC16 | c.24364G>T p.G8122* | Nonsense Mutation (SNP) | VAF 43/549 reads (8%) | called by muse, mutect2
- MUC5B | c.14702G>A p.G4901E | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO15A | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.246); called by muse, mutect2
- MYRFL | c.21T>A p.N7K | Missense Mutation (SNP) | VAF 20/407 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- NBPF15 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 90/419 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NIBAN3 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- NLRC5 | c.5111G>A p.G1704E | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP2 | c.3014C>T p.T1005I | Missense Mutation (SNP) | VAF 85/420 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOS1AP | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOX5 | c.2147G>A p.G716E | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NPAS1 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRL | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 127/503 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRL | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 126/505 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRN1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.221); called by muse, mutect2
- OBSCN | c.7954G>A p.A2652T | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR10AC1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 80/385 reads (21%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- OR2A12 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- OR2A2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 87/389 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR52E8 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2
- OVCH1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PABPC3 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 15/412 reads (4%) | called by muse, mutect2
- PAM | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 25/324 reads (8%) | called by muse, mutect2
- PAPOLB | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 15/441 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA1 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 11/366 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCGF3 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PCSK5 | c.3896G>A p.G1299E | Missense Mutation (SNP) | VAF 93/253 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCSK9 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2
- PDIA5 | c.664_668del p.Y222Rfs*11 | Frame Shift Del (DEL) | VAF 76/334 reads (23%) | called by mutect2, pindel, varscan2
- PEG3 | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHTF1 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3R3 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PLEKHH2 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLEKHN1 | c.946G>A p.G316R (on ENST00000379409; = p.G264R on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PNPO | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- POGLUT3 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- POTEE | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2
- POTEE | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- PPIP5K2 | c.205T>A p.L69I | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRKX | c.245T>C p.I82T | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PRLHR | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.151); called by muse, mutect2
- PRMT6 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- PTPN6 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 43/340 reads (13%) | called by muse, mutect2, varscan2
- PTPRO | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPRT | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTX4 | c.688C>T p.L230F (on ENST00000447419 / NM_001328608.2; = p.L225F on NM_001013658.1) | Missense Mutation (SNP) | VAF 113/460 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PWWP3B | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 33/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PYGO2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PZP | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RAB34 | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- RAD54B | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- RASGEF1B | c.854T>G p.M285R | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- RBM15 | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- RHOT2 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 83/364 reads (23%) | called by muse, mutect2, varscan2
- RIPOR2 | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNASEH2C | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 88/355 reads (25%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- RSPRY1 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL9 | c.2452A>T p.M818L | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.5182C>T p.P1728S | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SACS | c.6353G>A p.G2118E | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SACS | c.6352G>A p.G2118R | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SALL1 | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 77/365 reads (21%) | called by muse, mutect2, varscan2
- SAMSN1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SEC24D | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SELENOS | c.485-6_490del p.X162_splice | Splice Site (DEL) | VAF 37/272 reads (14%) | called by mutect2, pindel, varscan2
- SETD1A | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2
- SIGLEC10 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 17/516 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.124); called by muse, mutect2
- SIRT4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2
- SIX3 | c.997T>A p.*333Rext*1 | Nonstop Mutation (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- SLAIN2 | c.1514T>C p.M505T | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC19A3 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC22A9 | c.827C>A p.S276* | Nonsense Mutation (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- SLC2A4 | c.150G>A p.K50= | Splice Region (SNP) | VAF 47/187 reads (25%) | called by muse, mutect2, varscan2
- SLC41A3 | c.1444T>C p.F482L | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC44A5 | c.857T>A p.I286K | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- SNRPN | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- SNX30 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SOX7 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPRR3 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 127/557 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPTBN4 | c.4953G>A p.K1651= | Splice Region (SNP) | VAF 39/186 reads (21%) | called by muse, mutect2, varscan2
- ST6GALNAC6 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 88/308 reads (29%) | PolyPhen benign (0.299); called by muse, mutect2, varscan2
- STAC | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STARD8 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.357); called by muse, mutect2
- STARD8 | c.2576C>A p.P859H | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- SUGP2 | c.2548C>T p.L850F | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- SULT6B1 | c.478C>T p.P160S (on ENST00000535679 / NM_001367551.1; = p.P122S on NM_001032377.2) | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYNDIG1L | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SYNE1 | c.22764T>G p.S7588R (on ENST00000367255 / NM_182961.4; = p.S7517R on NM_033071.3) | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SYNE2 | c.15136G>A p.D5046N | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- SZT2 | c.9673C>T p.P3225S (on ENST00000634258 / NM_001365999.1; = p.P3168S on NM_015284.4) | Missense Mutation (SNP) | VAF 86/427 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAB2 | c.98T>G p.L33* | Nonsense Mutation (SNP) | VAF 54/203 reads (27%) | called by muse, mutect2, varscan2
- TAS2R38 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TBL1X | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBL3 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TENM3 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.019); called by muse, mutect2
- TEX10 | c.2039A>G p.Y680C | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLR7 | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 52/490 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.153); called by muse, mutect2
- TMEM79 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 16/513 reads (3%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); called by muse, mutect2
- TMEM97 | c.509A>T p.E170V | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TMPRSS12 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMPRSS15 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMPRSS9 | c.2383G>A p.G795S (on ENST00000648592; = p.G761S on NM_182973.2) | Missense Mutation (SNP) | VAF 90/464 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TNFRSF8 | c.1042A>T p.T348S | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TPH1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRANK1 | c.6142C>T p.L2048F | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TRAV9-1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- TRHDE | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRPC5 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTBK1 | c.2610G>T p.E870D | Missense Mutation (SNP) | VAF 74/397 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TXNRD1 | c.472C>T p.P158S (on ENST00000525566 / NM_001093771.3; = p.P60S on NM_003330.4) | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBQLN2 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 61/416 reads (15%) | called by muse, mutect2, varscan2
- UHRF1 | c.706G>C p.G236R (on ENST00000612630 / NM_001290050.1; = p.G249R on NM_013282.4) | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 73/320 reads (23%) | called by muse, mutect2, varscan2
- UQCRHL | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 108/542 reads (20%) | called by muse, mutect2
- USP16 | c.2329C>T p.L777F | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- VPS11 | c.965A>G p.K322R (on ENST00000620429; = p.K866R on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- VPS72 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- VPS72 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- WDFY3 | c.3355C>A p.P1119T | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.167); called by muse, mutect2
- WDR44 | c.1737G>A p.G579= | Splice Region (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- WNK3 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNT6 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 89/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WRAP53 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 98/461 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- WSCD2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR9 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XRRA1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZAN | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 52/472 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZDBF2 | c.2473T>C p.C825R | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFHX4 | c.10081A>G p.N3361D | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZMAT1 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZMYM3 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 24/530 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- ZNF185 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZNF208 | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ZNF226 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF26 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ZNF334 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF354B | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 61/270 reads (23%) | called by muse, mutect2, varscan2
- ZNF407 | c.5263G>A p.E1755K | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF592 | c.2944G>A p.G982S | Missense Mutation (SNP) | VAF 103/481 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF608 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF615 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ZNF711 | c.2248C>T p.Q750* | Nonsense Mutation (SNP) | VAF 51/281 reads (18%) | called by muse, mutect2, varscan2
- ZNF98 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 70/393 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ZZEF1 | c.7092G>A p.K2364= | Splice Region (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- AC098582.1 | c.1365C>T p.I455= | Silent (SNP) | VAF 35/206 reads (17%) | catalogued as COSV52025571; called by muse, varscan2
- ACOXL | c.198G>A p.R66= | Silent (SNP) | VAF 77/342 reads (23%) | called by muse, mutect2, varscan2
- ACTRT1 | c.405C>T p.F135= | Silent (SNP) | VAF 16/530 reads (3%) | called by muse, mutect2
- ADAM11 | c.213C>T p.V71= | Silent (SNP) | VAF 65/307 reads (21%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1137G>A p.R379= | Silent (SNP) | VAF 62/285 reads (22%) | catalogued as COSV58445692; called by muse, mutect2, varscan2
- ADGRL2 | c.2502G>A p.R834= (on ENST00000370717 / NM_001366005.1; = p.R821= on NM_012302.4) | Silent (SNP) | VAF 11/284 reads (4%) | called by muse, mutect2
- ADPRHL1 | c.546C>T p.F182= | Silent (SNP) | VAF 79/332 reads (24%) | catalogued as rs771184612, COSV100733467; called by muse, mutect2, varscan2
- ALDH1B1 | c.546C>T p.I182= | Silent (SNP) | VAF 21/345 reads (6%) | catalogued as rs1321260900; called by muse, mutect2
- AMPH | c.498C>T p.I166= | Silent (SNP) | VAF 37/220 reads (17%) | catalogued as COSV57753184; called by muse, mutect2, varscan2
- ANK3 | c.7491G>A p.G2497= | Silent (SNP) | VAF 32/289 reads (11%) | called by muse, mutect2, varscan2
- ANKFN1 | c.531C>T p.P177= | Silent (SNP) | VAF 92/394 reads (23%) | called by muse, mutect2, varscan2
- ANKRD44 | c.1293C>T p.F431= | Silent (SNP) | VAF 69/343 reads (20%) | called by muse, mutect2, varscan2
- AP2A1 | c.1572C>T p.S524= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- AP3B2 | c.1782C>T p.A594= | Silent (SNP) | VAF 16/390 reads (4%) | called by muse, mutect2
- AP4B1 | c.1836C>T p.L612= | Silent (SNP) | VAF 14/269 reads (5%) | called by muse, mutect2
- APH1B | c.468C>T p.F156= | Silent (SNP) | VAF 15/284 reads (5%) | called by muse, mutect2
- APLN | c.177G>A p.R59= | Silent (SNP) | VAF 37/291 reads (13%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.3663G>A p.K1221= | Silent (SNP) | VAF 8/221 reads (4%) | catalogued as rs998451572; called by muse, mutect2
- ARHGAP32 | c.5562C>T p.S1854= (on ENST00000310343 / NM_001378025.1; = p.S1505= on NM_014715.4) | Silent (SNP) | VAF 97/402 reads (24%) | catalogued as rs745771285; called by muse, mutect2, varscan2
- ASB10 | c.1057C>T p.L353= (on ENST00000420175 / NM_001142459.2; = p.L338= on NM_080871.4) | Silent (SNP) | VAF 34/344 reads (10%) | called by muse, mutect2
- ASXL1 | c.1791C>T p.I597= | Silent (SNP) | VAF 100/363 reads (28%) | called by muse, mutect2, varscan2
- ATG2A | c.1872C>T p.P624= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- ATP8A1 | c.3030G>A p.A1010= | Silent (SNP) | VAF 17/313 reads (5%) | catalogued as rs1369073845, COSV52536454; called by muse, mutect2
- ATP8A1 | c.2763G>A p.L921= | Silent (SNP) | VAF 57/263 reads (22%) | catalogued as rs1417057680, COSV100044584; called by muse, mutect2, varscan2
- BAHD1 | c.2025G>A p.Q675= | Silent (SNP) | VAF 87/323 reads (27%) | called by muse, mutect2, varscan2
- BASP1 | c.558C>T p.T186= | Silent (SNP) | VAF 76/328 reads (23%) | catalogued as rs1172971928; called by muse, mutect2, varscan2
- BCL9L | c.894C>T p.T298= | Silent (SNP) | VAF 11/364 reads (3%) | called by muse, mutect2
- BDKRB1 | c.684C>T p.S228= | Silent (SNP) | VAF 13/453 reads (3%) | catalogued as COSV53707408; called by muse, mutect2
- BEST3 | c.834C>T p.L278= | Silent (SNP) | VAF 60/218 reads (28%) | catalogued as rs1472361285; called by muse, mutect2, varscan2
- BEST3 | c.504G>A p.R168= | Silent (SNP) | VAF 22/221 reads (10%) | catalogued as COSV99876133; called by muse, mutect2, varscan2
- BPIFB4 | c.552C>A p.L184= | Silent (SNP) | VAF 126/421 reads (30%) | called by muse, mutect2, varscan2
- C12orf43 | c.483C>T p.C161= | Silent (SNP) | VAF 55/235 reads (23%) | called by muse, varscan2
- C2orf81 | c.1248C>T p.F416= | Silent (SNP) | VAF 39/377 reads (10%) | called by muse, mutect2, varscan2
- C9 | c.207C>T p.V69= | Silent (SNP) | VAF 50/266 reads (19%) | catalogued as rs1002887256; called by muse, mutect2, varscan2
- CA10 | c.276G>A p.R92= | Silent (SNP) | VAF 12/244 reads (5%) | catalogued as COSV53365603; called by muse, mutect2
- CALHM4 | c.327G>A p.G109= | Silent (SNP) | VAF 32/299 reads (11%) | called by muse, mutect2, varscan2
- CENPT | c.1644C>T p.I548= | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as COSV54649949; called by muse, mutect2, varscan2
- CFAP157 | c.651G>A p.T217= | Silent (SNP) | VAF 16/368 reads (4%) | catalogued as rs1417544473, COSV58854794; called by muse, mutect2
- CFAP54 | c.4848C>T p.I1616= | Silent (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- CFAP54 | c.6405C>T p.S2135= | Silent (SNP) | VAF 50/205 reads (24%) | called by muse, mutect2, varscan2
- CHD6 | c.4620C>T p.Y1540= | Silent (SNP) | VAF 93/437 reads (21%) | called by muse, mutect2, varscan2
- CHRD | c.2265C>T p.P755= | Silent (SNP) | VAF 76/402 reads (19%) | catalogued as rs141541705, COSV99201013; called by muse, mutect2, varscan2
- CKAP5 | c.3936C>T p.I1312= | Silent (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- CLCN1 | c.2232C>T p.P744= | Silent (SNP) | VAF 57/327 reads (17%) | called by muse, mutect2, varscan2
- CLDN5 | c.57G>A p.G19= (on ENST00000618236 / NM_001363066.2; = p.G104= on NM_003277.4) | Silent (SNP) | VAF 96/473 reads (20%) | catalogued as rs1268757776; called by muse, mutect2, varscan2
- CMKLR1 | c.166C>T p.L56= (on ENST00000312143 / NM_001142344.2; = p.L54= on NM_004072.3) | Silent (SNP) | VAF 97/406 reads (24%) | catalogued as COSV56439456, COSV56441754; called by muse, mutect2, varscan2
- CMYA5 | c.2787C>T p.S929= | Silent (SNP) | VAF 84/363 reads (23%) | catalogued as COSV71404469; called by muse, mutect2, varscan2
- CNGA4 | c.1027C>T p.L343= | Silent (SNP) | VAF 98/383 reads (26%) | called by muse, mutect2, varscan2
- CNR2 | c.1005C>T p.S335= | Silent (SNP) | VAF 106/358 reads (30%) | catalogued as rs1197456429; called by muse, mutect2, varscan2
- CNTN2 | c.2349C>T p.P783= | Silent (SNP) | VAF 16/400 reads (4%) | catalogued as COSV100085441; called by muse, mutect2
- COL2A1 | c.1101C>T p.F367= | Silent (SNP) | VAF 80/372 reads (22%) | catalogued as rs1277537589; called by muse, mutect2, varscan2
- COX18 | c.825C>T p.P275= | Silent (SNP) | VAF 54/203 reads (27%) | catalogued as COSV99887046; called by muse, mutect2, varscan2
- CRLF1 | c.651G>A p.L217= | Silent (SNP) | VAF 14/360 reads (4%) | called by muse, mutect2
- CUX2 | c.3078G>A p.K1026= | Silent (SNP) | VAF 87/435 reads (20%) | catalogued as COSV55648156; called by muse, mutect2, varscan2
- CYP4F12 | c.297C>T p.I99= | Silent (SNP) | VAF 44/230 reads (19%) | catalogued as rs369774036; called by muse, mutect2, varscan2
- DCANP1 | c.216G>A p.R72= | Silent (SNP) | VAF 13/365 reads (4%) | called by muse, mutect2
- DDX53 | c.702G>A p.L234= | Silent (SNP) | VAF 38/338 reads (11%) | called by muse, mutect2, varscan2
- DEPDC7 | c.1056C>T p.F352= (on ENST00000241051 / NM_001077242.2; = p.F343= on NM_139160.2) | Silent (SNP) | VAF 24/202 reads (12%) | catalogued as COSV53809113; called by muse, mutect2, varscan2
- DGCR8 | c.1533C>T p.S511= | Silent (SNP) | VAF 42/285 reads (15%) | catalogued as rs144592551; called by muse, mutect2, varscan2
- DGUOK | c.621C>T p.A207= | Silent (SNP) | VAF 63/266 reads (24%) | catalogued as rs955629513; called by muse, mutect2, varscan2
- DIMT1 | c.363C>T p.F121= | Silent (SNP) | VAF 64/300 reads (21%) | catalogued as rs371596528; called by muse, mutect2, varscan2
- DNAH5 | c.2826G>A p.T942= | Silent (SNP) | VAF 83/329 reads (25%) | catalogued as rs768837837, COSV54227051; called by muse, varscan2
- DNASE1L1 | c.105C>T p.A35= | Silent (SNP) | VAF 91/316 reads (29%) | called by muse, mutect2, varscan2
- DOCK7 | c.5745T>C p.Y1915= (on ENST00000635253 / NM_001367561.1; = p.Y1884= on NM_033407.3) | Silent (SNP) | VAF 52/217 reads (24%) | called by muse, mutect2, varscan2
- DOCK9 | c.1866G>A p.E622= (on ENST00000376460 / NM_001366676.2; = p.E623= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/400 reads (20%) | called by muse, mutect2, varscan2
- DPY19L1 | c.738T>A p.I246= | Silent (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- DSC1 | c.1743G>A p.V581= | Silent (SNP) | VAF 69/316 reads (22%) | called by muse, mutect2, varscan2
- DSCAM | c.618G>A p.E206= | Silent (SNP) | VAF 71/320 reads (22%) | called by muse, mutect2, varscan2
- DUSP10 | c.909C>T p.A303= | Silent (SNP) | VAF 141/412 reads (34%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.2631C>T p.I877= | Silent (SNP) | VAF 55/402 reads (14%) | called by muse, mutect2, varscan2
- EFTUD2 | c.1107C>T p.F369= | Silent (SNP) | VAF 71/282 reads (25%) | catalogued as rs760770880, COSV68183671; called by muse, mutect2, varscan2
- ELL | c.1401G>A p.R467= | Silent (SNP) | VAF 19/410 reads (5%) | called by muse, mutect2
- EPS15 | c.258A>G p.G86= | Silent (SNP) | VAF 100/360 reads (28%) | called by muse, mutect2, varscan2
- ERC2 | c.2196C>T p.I732= | Silent (SNP) | VAF 58/265 reads (22%) | catalogued as rs1207007057, COSV55597231; called by muse, mutect2, varscan2
- ESPL1 | c.2826C>T p.S942= | Silent (SNP) | VAF 67/308 reads (22%) | catalogued as rs749684440; called by muse, mutect2, varscan2
- ESRRG | c.144C>T p.S48= | Silent (SNP) | VAF 86/463 reads (19%) | catalogued as COSV100753320; called by muse, mutect2, varscan2
- EXD3 | c.882G>A p.G294= | Silent (SNP) | VAF 64/186 reads (34%) | called by muse, mutect2, varscan2
- EXOC7 | c.924G>A p.R308= | Silent (SNP) | VAF 44/211 reads (21%) | catalogued as rs1221508053; called by muse, mutect2, varscan2
- F9 | c.1080C>T p.F360= | Silent (SNP) | VAF 93/363 reads (26%) | called by muse, mutect2, varscan2
- FAM186A | c.2166C>T p.F722= | Silent (SNP) | VAF 59/293 reads (20%) | called by muse, mutect2, varscan2
- FAM234A | c.1617C>T p.I539= | Silent (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- FAM47B | c.435C>T p.L145= | Silent (SNP) | VAF 51/394 reads (13%) | catalogued as COSV100264251; called by muse, mutect2, varscan2
- FAM71A | c.1209C>T p.S403= | Silent (SNP) | VAF 102/472 reads (22%) | called by muse, mutect2, varscan2
- FAM83H | c.1644C>T p.F548= | Silent (SNP) | VAF 16/474 reads (3%) | called by muse, mutect2
- FAT2 | c.11811G>A p.E3937= | Silent (SNP) | VAF 86/422 reads (20%) | called by muse, mutect2
- FAT2 | c.9030G>A p.Q3010= | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as COSV99942050; called by muse, mutect2, varscan2
- FCRL1 | c.1269G>A p.V423= | Silent (SNP) | VAF 12/271 reads (4%) | catalogued as COSV63827295; called by muse, mutect2
- FCRL5 | c.1395C>T p.S465= | Silent (SNP) | VAF 33/206 reads (16%) | catalogued as rs926826526, COSV62521968; called by muse, mutect2, varscan2
- FGF2 | c.474C>T p.H158= | Silent (SNP) | VAF 74/284 reads (26%) | called by mutect2, varscan2
- FLNA | c.2151C>T p.C717= | Silent (SNP) | VAF 36/271 reads (13%) | called by muse, mutect2, varscan2
- FLT1 | c.942G>A p.R314= | Silent (SNP) | VAF 72/331 reads (22%) | catalogued as COSV99147138; called by muse, mutect2, varscan2
- FMN2 | c.921C>T p.L307= | Silent (SNP) | VAF 44/612 reads (7%) | catalogued as rs1177064949, COSV60426869; called by muse, mutect2
- FOXO4 | c.288C>T p.S96= | Silent (SNP) | VAF 62/376 reads (16%) | called by muse, varscan2
- FOXQ1 | c.327A>G p.A109= | Silent (SNP) | VAF 59/379 reads (16%) | called by muse, mutect2, varscan2
- FRG2C | c.624G>A p.L208= | Silent (SNP) | VAF 91/1399 reads (7%) | catalogued as rs1179508202; called by muse, mutect2
- FST | c.549G>A p.Q183= | Silent (SNP) | VAF 15/353 reads (4%) | catalogued as COSV56816571; called by muse, mutect2
- GALNT15 | c.627G>A p.R209= | Silent (SNP) | VAF 78/328 reads (24%) | catalogued as COSV60215032; called by muse, mutect2, varscan2
- GCKR | c.774C>T p.S258= | Silent (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- GCKR | c.1623G>A p.A541= | Silent (SNP) | VAF 77/353 reads (22%) | catalogued as rs146520140; called by muse, mutect2, varscan2
- GGT5 | c.1218C>T p.T406= | Silent (SNP) | VAF 58/282 reads (21%) | called by muse, mutect2, varscan2
- GHRHR | c.1230G>A p.T410= | Silent (SNP) | VAF 73/244 reads (30%) | catalogued as rs752346076, COSV58195464; called by muse, mutect2, varscan2
- GLI1 | c.2325C>T p.P775= | Silent (SNP) | VAF 25/439 reads (6%) | catalogued as rs1297252492; called by muse, mutect2
- GLRA2 | c.351G>A p.L117= | Silent (SNP) | VAF 30/478 reads (6%) | called by muse, mutect2
- GLRA3 | c.234C>T p.I78= | Silent (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- GPBP1L1 | c.39C>T p.F13= | Silent (SNP) | VAF 88/387 reads (23%) | catalogued as rs1198360852; called by muse, mutect2, varscan2
- GPI | c.1347C>T p.L449= | Silent (SNP) | VAF 59/249 reads (24%) | called by muse, mutect2, varscan2
- GPR35 | c.225C>T p.F75= | Silent (SNP) | VAF 51/341 reads (15%) | catalogued as rs372508109; called by muse, mutect2, varscan2
- GPR37L1 | c.144C>A p.T48= | Silent (SNP) | VAF 50/568 reads (9%) | called by muse, mutect2
- GRIN2A | c.1356G>A p.V452= | Silent (SNP) | VAF 30/305 reads (10%) | called by muse, mutect2, varscan2
- GRIN2A | c.735C>T p.S245= | Silent (SNP) | VAF 94/382 reads (25%) | catalogued as rs760446221; called by muse, mutect2, varscan2
- GRM3 | c.2406C>T p.T802= | Silent (SNP) | VAF 71/271 reads (26%) | called by muse, mutect2, varscan2
- GSDME | c.165C>T p.S55= | Silent (SNP) | VAF 14/375 reads (4%) | called by muse, mutect2
- HAVCR1 | c.462G>A p.T154= | Silent (SNP) | VAF 85/338 reads (25%) | catalogued as rs192652646, COSV59401042, COSV59401547; called by muse, mutect2, varscan2
- HHIPL1 | c.1581C>T p.T527= | Silent (SNP) | VAF 80/349 reads (23%) | called by muse, mutect2, varscan2
- HNRNPUL2 | c.1677G>A p.V559= | Silent (SNP) | VAF 20/462 reads (4%) | called by muse, mutect2
- HOXD8 | c.240G>A p.G80= | Silent (SNP) | VAF 39/418 reads (9%) | called by muse, mutect2
- IDH1 | c.1146T>C p.G382= | Silent (SNP) | VAF 28/215 reads (13%) | called by muse, mutect2, varscan2
- IDO2 | c.964C>T p.L322= (on ENST00000389060; = p.L335= on NM_194294.2) | Silent (SNP) | VAF 82/297 reads (28%) | called by muse, mutect2, varscan2
- IFIH1 | c.66G>A p.V22= | Silent (SNP) | VAF 75/330 reads (23%) | called by muse, mutect2, varscan2
- IGFN1 | c.3000C>T p.G1000= (on ENST00000295591 / NM_001367841.1; = p.G3457= on NM_001164586.2) | Silent (SNP) | VAF 72/383 reads (19%) | called by muse, mutect2, varscan2
- IGHV1-18 | c.141C>T p.T47= | Silent (SNP) | VAF 84/341 reads (25%) | catalogued as rs150020365; called by muse, mutect2, varscan2
- IGHV3-30 | c.27C>T p.F9= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- IGHV7-81 | c.87G>A p.E29= | Silent (SNP) | VAF 17/390 reads (4%) | catalogued as rs1401112784; called by muse, mutect2
- IGLV3-22 | c.240C>T p.F80= | Silent (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- IMPG2 | c.2889T>C p.S963= | Silent (SNP) | VAF 89/377 reads (24%) | called by muse, mutect2, varscan2
- INPP5D | c.3519C>T p.H1173= (on ENST00000445964 / NM_001017915.3; = p.H1172= on NM_005541.5) | Silent (SNP) | VAF 99/451 reads (22%) | catalogued as rs556901773; called by muse, mutect2, varscan2
- INPP5J | c.2997G>A p.L999= (on ENST00000331075 / NM_001284285.2; = p.L631= on NM_001002837.2) | Silent (SNP) | VAF 75/380 reads (20%) | catalogued as COSV53208964; called by muse, mutect2, varscan2
- INSM2 | c.549C>T p.P183= | Silent (SNP) | VAF 18/386 reads (5%) | called by muse, mutect2
- IQCA1 | c.762C>T p.I254= | Silent (SNP) | VAF 68/267 reads (25%) | called by muse, mutect2, varscan2
- JAG1 | c.1752C>T p.S584= | Silent (SNP) | VAF 69/270 reads (26%) | called by muse, mutect2, varscan2
- KCNAB1 | c.222C>T p.L74= | Silent (SNP) | VAF 93/364 reads (26%) | catalogued as rs759022544; called by muse, mutect2, varscan2
- KCNH7 | c.2235C>T p.A745= | Silent (SNP) | VAF 83/343 reads (24%) | catalogued as COSV59810344; called by muse, mutect2, varscan2
- KDR | c.4044G>A p.G1348= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- KIAA1549L | c.561C>T p.A187= (on ENST00000321505; = p.A484= on NM_012194.3) | Silent (SNP) | VAF 39/362 reads (11%) | catalogued as COSV55782238; called by muse, mutect2, varscan2
- KIF26B | c.3924G>A p.E1308= | Silent (SNP) | VAF 27/645 reads (4%) | called by muse, mutect2
- KLHL33 | c.771T>C p.P257= | Silent (SNP) | VAF 83/404 reads (21%) | called by muse, mutect2, varscan2
- L1CAM | c.2313C>T p.P771= | Silent (SNP) | VAF 16/454 reads (4%) | catalogued as CD000936; called by muse, mutect2
- LAMA2 | c.357C>T p.I119= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as rs373866593; called by muse, mutect2, varscan2
- LCT | c.1137G>A p.Q379= | Silent (SNP) | VAF 106/367 reads (29%) | called by muse, mutect2, varscan2
- LCT | c.1053G>A p.T351= | Silent (SNP) | VAF 99/366 reads (27%) | catalogued as rs1029530520, COSV51550012; called by muse, mutect2, varscan2
- LGI2 | c.300C>T p.I100= | Silent (SNP) | VAF 55/288 reads (19%) | called by muse, mutect2, varscan2
- LMTK3 | c.3078C>T p.A1026= | Silent (SNP) | VAF 125/459 reads (27%) | called by muse, mutect2, varscan2
- LRP5 | c.4302C>T p.P1434= | Silent (SNP) | VAF 93/321 reads (29%) | catalogued as rs1370406220; called by muse, mutect2, varscan2
- LUZP1 | c.1698C>T p.A566= | Silent (SNP) | VAF 30/296 reads (10%) | called by muse, mutect2, varscan2
- LYPD4 | c.312C>T p.A104= | Silent (SNP) | VAF 13/433 reads (3%) | called by muse, mutect2
- LZTS3 | c.1995C>T p.L665= (on ENST00000329152; = p.L619= on NM_001282533.2) | Silent (SNP) | VAF 73/277 reads (26%) | catalogued as rs539198242; called by muse, mutect2, varscan2
- MAP3K6 | c.948C>T p.F316= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- MAP4K2 | c.831C>T p.L277= | Silent (SNP) | VAF 35/275 reads (13%) | catalogued as rs1180673961; called by muse, mutect2, varscan2
- MAPK8IP1 | c.411C>T p.S137= | Silent (SNP) | VAF 69/270 reads (26%) | called by muse, mutect2, varscan2
- MARCHF8 | c.601T>C p.L201= | Silent (SNP) | VAF 64/268 reads (24%) | called by muse, mutect2, varscan2
- MCM5 | c.1698C>T p.C566= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as rs1414225953; called by muse, mutect2
- MDM1 | c.84C>T p.S28= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- MED12 | c.567C>T p.I189= | Silent (SNP) | VAF 32/225 reads (14%) | catalogued as COSV61356661; called by muse, mutect2, varscan2
- MEOX1 | c.594G>A p.R198= | Silent (SNP) | VAF 68/290 reads (23%) | catalogued as rs1468918100, COSV100233673; called by muse, mutect2, varscan2
- MGA | c.4899C>T p.T1633= | Silent (SNP) | VAF 33/279 reads (12%) | catalogued as COSV99580256; called by muse, mutect2, varscan2
- MRGPRX4 | c.153C>T p.L51= | Silent (SNP) | VAF 96/386 reads (25%) | called by muse, mutect2
- MROH1 | c.102C>T p.S34= | Silent (SNP) | VAF 35/362 reads (10%) | catalogued as rs267601824; called by muse, mutect2
- MSTO1 | c.903C>T p.S301= | Silent (SNP) | VAF 26/412 reads (6%) | catalogued as rs1029582017; called by muse, mutect2
- MUC5B | c.14703G>A p.G4901= | Silent (SNP) | VAF 93/386 reads (24%) | called by muse, mutect2, varscan2
- MYH13 | c.867C>T p.Y289= | Silent (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- NEU3 | c.1126C>T p.L376= | Silent (SNP) | VAF 29/282 reads (10%) | called by muse, mutect2, varscan2
- NEUROD4 | c.96G>A p.K32= | Silent (SNP) | VAF 53/209 reads (25%) | catalogued as rs1407421078, COSV99669902; called by muse, varscan2
- NOL4 | c.1488T>A p.A496= | Silent (SNP) | VAF 64/308 reads (21%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5239C>T p.L1747= | Silent (SNP) | VAF 42/300 reads (14%) | called by muse, mutect2, varscan2
- NPC1 | c.3445C>T p.L1149= | Silent (SNP) | VAF 71/276 reads (26%) | called by muse, mutect2, varscan2
- NPR3 | c.633G>A p.R211= | Silent (SNP) | VAF 59/303 reads (19%) | called by muse, mutect2, varscan2
- NR0B2 | c.336C>T p.A112= | Silent (SNP) | VAF 75/316 reads (24%) | catalogued as rs780927538; called by muse, mutect2, varscan2
- NR2C1 | c.627C>T p.I209= | Silent (SNP) | VAF 75/368 reads (20%) | called by muse, mutect2, varscan2
- NRXN1 | c.639G>A p.G213= | Silent (SNP) | VAF 102/475 reads (21%) | catalogued as COSV68004491; called by muse, mutect2, varscan2
- NRXN2 | c.4050G>A p.A1350= | Silent (SNP) | VAF 54/367 reads (15%) | catalogued as rs761962421, COSV55457036; called by muse, mutect2, varscan2
- NT5C1B | c.24G>A p.Q8= | Silent (SNP) | VAF 53/285 reads (19%) | catalogued as COSV58397047; called by muse, mutect2, varscan2
- NUTM2B | c.1335G>A p.E445= | Silent (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2
- NYNRIN | c.3822C>T p.L1274= | Silent (SNP) | VAF 83/341 reads (24%) | catalogued as rs754599205, COSV66841485; called by muse, mutect2, varscan2
- OBSCN | c.7953G>A p.K2651= | Silent (SNP) | VAF 51/303 reads (17%) | called by muse, mutect2, varscan2
- OR10AG1 | c.207C>T p.I69= | Silent (SNP) | VAF 64/248 reads (26%) | catalogued as COSV56633651; called by muse, mutect2, varscan2
- OR1N1 | c.528C>T p.F176= | Silent (SNP) | VAF 79/254 reads (31%) | called by muse, mutect2
- OR2W1 | c.204C>T p.F68= | Silent (SNP) | VAF 61/284 reads (21%) | called by muse, mutect2, varscan2
- OR51A4 | c.54G>A p.G18= | Silent (SNP) | VAF 34/321 reads (11%) | catalogued as rs1329758844; called by muse, mutect2, varscan2
- OR56A5 | c.625C>T p.L209= | Silent (SNP) | VAF 97/358 reads (27%) | called by muse, mutect2, varscan2
- OR6C76 | c.145C>T p.L49= | Silent (SNP) | VAF 35/341 reads (10%) | called by muse, mutect2, varscan2
152 further variants in this file (0 protein-altering or splice-affecting, 120 silent, 32 other) are not listed here.
